Somatic mutation profile of tumor specimen MP2PRT-PASWUK-TMP1-A (aliquot MP2PRT-PASWUK-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASWUK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,779 days).
Specimen MP2PRT-PASWUK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 492db016-69a5-45c5-bc8c-31df49ec11a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWUK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWUK-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f69b49ee-3e99-4509-8c98-b526e0b3cf27

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 8 silent.
By variant classification: Silent 8, Missense Mutation 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/260 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 39/220 reads (18%) | catalogued as rs777379656; called by muse, mutect2, varscan2
- BMP4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 72/1134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs889958974, COSV55416421; called by muse, mutect2
- CEACAM20 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 131/354 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs771423208, COSV57601051; called by muse, mutect2, varscan2
- SLC7A4 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 213/585 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs375764105, COSV100298658; called by muse, mutect2, varscan2
- TRRAP | c.10906G>A p.D3636N (on ENST00000359863 / NM_001244580.1; = p.D3607N on NM_003496.3) | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV62815692; called by muse, mutect2, varscan2
- FSCB | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 132/621 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SLC45A1 | c.117_118del p.H41Pfs*30 | Frame Shift Del (DEL) | VAF 139/508 reads (27%) | called by mutect2, pindel, varscan2
- WASHC2A | c.3412A>G p.T1138A | Missense Mutation (SNP) | VAF 168/743 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C7orf57 | c.333G>A p.P111= | Silent (SNP) | VAF 92/358 reads (26%) | catalogued as rs758724934, COSV62363759; called by muse, mutect2, varscan2
- CASP6 | c.387A>G p.A129= | Silent (SNP) | VAF 165/511 reads (32%) | catalogued as rs368031821; called by muse, mutect2, varscan2
- DSTYK | c.894C>T p.S298= | Silent (SNP) | VAF 91/266 reads (34%) | catalogued as rs376327322; called by muse, mutect2, varscan2
- FKBP10 | c.657G>T p.L219= | Silent (SNP) | VAF 158/621 reads (25%) | called by muse, mutect2, varscan2
- MROH2B | c.72G>A p.K24= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV101270864; called by muse, mutect2, varscan2
- MYH7 | c.3171C>T p.G1057= | Silent (SNP) | VAF 161/759 reads (21%) | catalogued as rs758822596, COSV62522075; called by muse, mutect2, varscan2
- RNASE1 | c.51G>T p.L17= | Silent (SNP) | VAF 42/632 reads (7%) | called by muse, mutect2
- SMIM28 | c.12G>C p.L4= | Silent (SNP) | VAF 117/496 reads (24%) | called by muse, mutect2, varscan2
